Somatic mutation profile of tumor specimen TARGET-10-PATXNK-09A (aliquot TARGET-10-PATXNK-09A-01D) from TARGET case TARGET-10-PATXNK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,428 days).
Specimen TARGET-10-PATXNK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46f9931c-af8f-4bf5-a05c-a68f512df460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATXNK-10A (Blood Derived Normal), aliquot TARGET-10-PATXNK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00b347a4-2eb5-43f8-9244-8d854fdfee11

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Ins 1, RNA 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC098582.1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52026973; called by muse, mutect2
- ACTN4 | c.2694C>A p.Y898* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV53152046; called by muse, mutect2, varscan2
- ARHGEF6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759340844, COSV51687739; called by muse, mutect2, varscan2
- CSRNP2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs765296308, COSV57335703; called by muse, mutect2, varscan2
- FLG | c.2316G>T p.Q772H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs751056562, COSV64252797; called by muse, mutect2, varscan2
- ITGA8 | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV65224704; called by muse, mutect2, varscan2
- LAMA1 | c.8619G>C p.K2873N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV67546287; called by muse, mutect2, varscan2
- METAP1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as rs1215017169, COSV56446779; called by muse, mutect2, varscan2
- MYB | c.40_41insGCCGTA p.E14delinsGRK | In Frame Ins (INS) | VAF 8/42 reads (19%) | catalogued as COSV57198855, COSV57201532, COSV57203337; called by mutect2, pindel, varscan2
- NOTCH1 | c.7318C>T p.Q2440* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53024887; called by muse, mutect2, varscan2
- PHF6 | c.802G>A p.V268I (on ENST00000332070 / NM_032458.3; = p.V269I on NM_032335.3) | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59707677; called by muse, mutect2, varscan2
- PTEN | c.697delinsGA p.R233Efs*10 | Frame Shift Ins (INS) | VAF 27/83 reads (33%) | catalogued as CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; called by pindel, varscan2*
- PTEN | c.738delinsTCCGC p.L247Pfs*7 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | catalogued as COSV64294002, COSV64297361, COSV64304156; called by pindel, varscan2*
- SAAL1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs368016177; called by muse, mutect2, varscan2
- SHC4 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60118717; called by muse, mutect2, varscan2
- SOX5 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780562400, COSV58645912; called by muse, mutect2, varscan2
- TNRC6C | c.4161A>G p.P1387= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as rs753490243; called by muse, varscan2
- NOTCH1 | c.7525_7535del p.F2509Vfs*3 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- PLCH2 | c.528_529del p.Q176Hfs*3 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- ABCC3 | c.3360G>A p.V1120= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs777439043; called by muse, mutect2, varscan2
- EPHA5 | c.*104C>A | 3'UTR (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99898135; called by muse, mutect2, varscan2
- OR4C4P | n.307del | RNA (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- SETD9 | c.*135T>G | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
